Somatic mutation profile of tumor specimen ALCH-AC3M-TTR1-A (aliquot ALCH-AC3M-TTR1-A-1-0-D-A636-36) from ALCHEMIST case ALCH-AC3M, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 68.3 years (24,951 days).
Specimen ALCH-AC3M-TTR1-A: Sample type: FFPE Recurrent; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 12bb84e8-00a8-456b-9040-c2f7dd9de33e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AC3M-NB1-A (Blood Derived Normal), aliquot ALCH-AC3M-NB1-A-1-0-D-A49J-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/97c8a21a-5871-499e-a32b-693c71bdf419

The open-access MAF lists 493 somatic variants for this specimen: 319 protein-altering or splice-affecting, 108 silent, 66 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 262, Silent 108, Nonsense Mutation 35, Intron 28, RNA 12, Splice Site 10, 3'UTR 10, 5'UTR 7, Splice Region 7, 5'Flank 7, Frame Shift Del 4, 3'Flank 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 679/1608 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.488A>G p.Y163C | Missense Mutation (SNP) | VAF 161/356 reads (45%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs148924904, CM942135, COSV52663142, COSV52676381; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA5 | c.4279C>T p.Q1427* | Nonsense Mutation (SNP) | VAF 34/316 reads (11%) | catalogued as COSV67019739; called by muse, varscan2
- ADAD1 | c.536C>T p.P179L | Missense Mutation (SNP) | VAF 84/189 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.009); catalogued as rs1248212922; called by muse, mutect2, varscan2
- ADARB1 | c.1648C>T p.R550W (on ENST00000360697 / NM_001346687.2; = p.R510W on NM_001112.4) | Missense Mutation (SNP) | VAF 122/310 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62348097; called by muse, mutect2, varscan2
- AK5 | c.186G>T p.Q62H (on ENST00000354567 / NM_174858.3; = p.Q36H on NM_012093.4) | Missense Mutation (SNP) | VAF 26/162 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as COSV100481458; called by muse, varscan2
- AMY2A | c.586G>A p.E196K | Missense Mutation (SNP) | VAF 98/948 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.031); catalogued as rs750768619, COSV70215035; called by muse, mutect2, varscan2
- AP4M1 | c.130G>T p.E44* | Nonsense Mutation (SNP) | VAF 202/571 reads (35%) | catalogued as rs201424846; called by muse, mutect2, varscan2
- BICRA | c.115G>A p.G39R | Missense Mutation (SNP) | VAF 36/237 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.602); catalogued as rs375078723; called by muse, mutect2, varscan2
- C1QTNF3 | c.475G>A p.V159I | Missense Mutation (SNP) | VAF 38/258 reads (15%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.549); catalogued as COSV51468193; called by muse, mutect2, varscan2
- CACNA1F | c.5075C>T p.S1692F | Missense Mutation (SNP) | VAF 81/669 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.135); catalogued as COSV59906376; called by muse, mutect2, varscan2
- CACNA1G | c.826G>A p.E276K | Missense Mutation (SNP) | VAF 43/245 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as COSV100662708; called by muse, mutect2, varscan2
- CBFA2T2 | c.538-1G>C p.X180_splice | Splice Site (SNP) | VAF 59/271 reads (22%) | catalogued as COSV60076449; called by muse, mutect2, varscan2
- CDKN2A | c.55del p.A19Pfs*7 | Frame Shift Del (DEL) | VAF 67/172 reads (39%) | catalogued as CM127041; called by mutect2, pindel, varscan2
- CLDN19 | c.306G>T p.M102I | Missense Mutation (SNP) | VAF 135/691 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV56417591; called by muse, mutect2, varscan2
- CNR2 | c.1021G>A p.E341K | Missense Mutation (SNP) | VAF 28/262 reads (11%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.769); catalogued as rs1317764755; called by muse, varscan2
- CORIN | c.1187C>T p.T396M | Missense Mutation (SNP) | VAF 218/484 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.714); catalogued as rs369280273; called by muse, mutect2, varscan2
- CREB3L3 | c.634G>T p.E212* | Nonsense Mutation (SNP) | VAF 206/557 reads (37%) | catalogued as rs540604714, COSV99314453; called by muse, mutect2, varscan2
- CREBBP | c.2077C>G p.P693A | Missense Mutation (SNP) | VAF 171/407 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.281); catalogued as CD158352; called by muse, mutect2, varscan2
- CSMD3 | c.1633G>T p.V545L (on ENST00000297405 / NM_001363185.1; = p.V441L on NM_052900.3) | Missense Mutation (SNP) | VAF 138/559 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.264); catalogued as COSV99826970; called by muse, mutect2, varscan2
- CYP4F11 | c.1441G>T p.V481F | Missense Mutation (SNP) | VAF 131/356 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV56128032; called by muse, mutect2, varscan2
- DAB1 | c.1757C>A p.A586D (on ENST00000371231; = p.A553D on NM_021080.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); catalogued as rs751379532; called by muse, mutect2, varscan2
- DCLK3 | c.680G>C p.R227T | Missense Mutation (SNP) | VAF 80/463 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.01); catalogued as COSV69362940, COSV69364363; called by muse, mutect2, varscan2
- DGUOK | c.130G>T p.E44* | Nonsense Mutation (SNP) | VAF 176/422 reads (42%) | catalogued as rs762550967, CM0910816; called by muse, mutect2, varscan2
- DISP3 | c.434C>A p.S145Y | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.713); catalogued as COSV53834900; called by muse, mutect2, varscan2
- DMD | c.1021C>A p.L341M | Missense Mutation (SNP) | VAF 30/290 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55881876; called by muse, mutect2
- DNAAF2 | c.821C>T p.S274L | Missense Mutation (SNP) | VAF 45/223 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.542); catalogued as rs1317622174; called by muse, mutect2, varscan2
- DNAH7 | c.8737G>T p.G2913* | Nonsense Mutation (SNP) | VAF 147/309 reads (48%) | catalogued as COSV56781668; called by muse, mutect2, varscan2
- DPY19L2 | c.1540C>T p.R514C | Missense Mutation (SNP) | VAF 18/109 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.046); catalogued as rs1478776218, COSV60541920; called by muse, mutect2, varscan2
- ENDOV | c.692G>A p.R231Q | Missense Mutation (SNP) | VAF 103/619 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs139905366; called by muse, mutect2, varscan2
- FLNA | c.5074G>A p.D1692N (on ENST00000369850 / NM_001110556.2; = p.D1684N on NM_001456.3) | Missense Mutation (SNP) | VAF 97/484 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.02); catalogued as COSV61042819; called by muse, mutect2, varscan2
- FREM3 | c.2224T>C p.Y742H | Missense Mutation (SNP) | VAF 241/900 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1043830264; called by muse, mutect2, varscan2
- GABRB3 | c.676G>A p.A226T | Missense Mutation (SNP) | VAF 352/545 reads (65%) | SIFT tolerated (0.49); PolyPhen benign (0.007); catalogued as COSV54648691; called by muse, mutect2, varscan2
- GAS6 | c.320C>T p.S107L | Missense Mutation (SNP) | VAF 79/316 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.01); catalogued as COSV100582325; called by muse, mutect2, varscan2
- GLRA2 | c.1106G>A p.R369H | Missense Mutation (SNP) | VAF 17/173 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs777077152, COSV54341910; called by muse, mutect2, varscan2
- GRIK2 | c.1357C>G p.L453V | Missense Mutation (SNP) | VAF 77/254 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV59731424; called by muse, mutect2, varscan2
- GRIK3 | c.667C>T p.R223* | Nonsense Mutation (SNP) | VAF 80/270 reads (30%) | catalogued as rs971243250, COSV66142243; called by muse, mutect2, varscan2
- GUCY1A2 | c.912C>A p.N304K | Missense Mutation (SNP) | VAF 133/322 reads (41%) | SIFT tolerated (0.93); PolyPhen benign (0.01); catalogued as rs763966532; called by muse, mutect2, varscan2
- H4C12 | c.160G>T p.E54* | Nonsense Mutation (SNP) | VAF 44/224 reads (20%) | catalogued as COSV100694797; called by muse, mutect2, varscan2
- HAPLN1 | c.576C>A p.D192E | Missense Mutation (SNP) | VAF 87/126 reads (69%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV99164994; called by muse, mutect2, varscan2
- HMCN1 | c.3649C>T p.H1217Y | Missense Mutation (SNP) | VAF 180/785 reads (23%) | SIFT tolerated (0.54); PolyPhen benign (0.121); catalogued as COSV99633559; called by muse, mutect2, varscan2
- HOXD13 | c.58G>T p.G20C | Missense Mutation (SNP) | VAF 40/76 reads (53%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.233); catalogued as COSV66832416; called by muse, mutect2, varscan2
- IGHA1 | c.641C>T p.P214L | Missense Mutation (SNP) | VAF 113/175 reads (65%) | SIFT deleterious (0.02); PolyPhen benign (0.095); catalogued as rs767197822; called by muse, mutect2, varscan2
- KANK3 | c.808G>T p.D270Y | Missense Mutation (SNP) | VAF 16/91 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.233); catalogued as COSV58359806; called by muse, mutect2, varscan2
- KCNT2 | c.2743G>T p.G915* | Nonsense Mutation (SNP) | VAF 59/239 reads (25%) | catalogued as COSV99655057; called by muse, mutect2, varscan2
- KIF13B | c.936G>A p.W312* | Nonsense Mutation (SNP) | VAF 126/234 reads (54%) | catalogued as rs1563762226; called by muse, varscan2
- KLF17 | c.14C>A p.P5Q | Missense Mutation (SNP) | VAF 55/246 reads (22%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.073); catalogued as COSV64856162; called by muse, mutect2, varscan2
- KLHL14 | c.1499G>A p.R500Q | Missense Mutation (SNP) | VAF 58/342 reads (17%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.979); catalogued as rs780186069, COSV63833938; called by muse, mutect2, varscan2
- KLHL4 | c.1981G>T p.D661Y | Missense Mutation (SNP) | VAF 283/408 reads (69%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100910128; called by muse, mutect2, varscan2
- KRTAP10-10 | c.583C>T p.H195Y | Missense Mutation (SNP) | VAF 254/693 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.154); catalogued as COSV59956750; called by muse, mutect2, varscan2
- KRTAP6-3 | c.134G>A p.G45E | Missense Mutation (SNP) | VAF 96/505 reads (19%) | PolyPhen possibly damaging (0.448); catalogued as rs1181455960; called by muse, mutect2, varscan2
- LAMA2 | c.4959G>A p.R1653= | Splice Region (SNP) | VAF 296/450 reads (66%) | catalogued as COSV70352304; called by muse, mutect2, varscan2
- LILRA2 | c.472G>T p.G158* | Nonsense Mutation (SNP) | VAF 249/1051 reads (24%) | catalogued as COSV99254101, COSV99254151; called by muse, mutect2, varscan2
- LOXL3 | c.947G>T p.G316V | Missense Mutation (SNP) | VAF 57/181 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755179913; called by muse, mutect2, varscan2
- LRIT2 | c.140G>T p.G47V | Missense Mutation (SNP) | VAF 36/91 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.231); catalogued as COSV100928301; called by muse, mutect2, varscan2
- LRP6 | c.1709A>T p.D570V | Missense Mutation (SNP) | VAF 98/359 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV99742656; called by muse, mutect2, varscan2
- LYPD2 | c.47G>T p.C16F | Missense Mutation (SNP) | VAF 105/235 reads (45%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV63649493; called by muse, mutect2, varscan2
- MCCC1 | c.1882G>C p.E628Q | Missense Mutation (SNP) | VAF 103/560 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as CM125737, COSV55605978; called by muse, mutect2, varscan2
- MECOM | c.1832G>A p.G611E (on ENST00000468789 / NM_001105078.4; = p.G799E on NM_004991.4) | Missense Mutation (SNP) | VAF 94/456 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs267599684, COSV52962370; called by mutect2, varscan2
- MFSD2B | c.283G>C p.D95H | Missense Mutation (SNP) | VAF 160/367 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57855595; called by muse, mutect2, varscan2
- MGAT1 | c.559C>T p.R187C | Missense Mutation (SNP) | VAF 89/176 reads (51%) | PolyPhen probably damaging (1); catalogued as rs1184766082, COSV57133158; called by muse, mutect2, varscan2
- MS4A3 | c.13G>A p.E5K | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.022); catalogued as rs780015751, COSV53934738; called by muse, mutect2, varscan2
- MSLN | c.1702C>T p.R568W (on ENST00000382862 / NM_013404.4; = p.R560W on NM_005823.6) | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.138); catalogued as rs374380113; called by muse, mutect2, varscan2
- MUC17 | c.9538G>C p.E3180Q | Missense Mutation (SNP) | VAF 25/226 reads (11%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.932); catalogued as COSV60283767; called by muse, mutect2
- MYH13 | c.3424G>T p.D1142Y | Missense Mutation (SNP) | VAF 181/377 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99351577; called by muse, mutect2, varscan2
- NCOR2 | c.1277G>A p.R426H | Missense Mutation (SNP) | VAF 29/145 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs970975674; called by muse, mutect2, varscan2
- NLRP12 | c.2223C>A p.N741K | Missense Mutation (SNP) | VAF 94/282 reads (33%) | SIFT tolerated (0.5); PolyPhen benign (0.211); catalogued as rs781690422; called by muse, mutect2, varscan2
- NLRP3 | c.424G>T p.V142L | Missense Mutation (SNP) | VAF 184/628 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.612); catalogued as COSV100276704; called by muse, mutect2, varscan2
- NOS1 | c.2935G>T p.V979L | Missense Mutation (SNP) | VAF 123/241 reads (51%) | SIFT tolerated (0.31); PolyPhen benign (0.009); catalogued as COSV57608726; called by muse, mutect2, varscan2
- NPHS1 | c.741G>T p.W247C | Missense Mutation (SNP) | VAF 60/146 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs758490906; called by muse, mutect2, varscan2
- NPTX2 | c.778G>T p.A260S | Missense Mutation (SNP) | VAF 124/397 reads (31%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.545); catalogued as COSV55718898; called by muse, mutect2, varscan2
- NTN5 | c.672C>G p.N224K | Missense Mutation (SNP) | VAF 64/268 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.089); catalogued as rs371752057; called by muse, mutect2, varscan2
- OBSCN | c.17082G>A p.L5694= | Splice Region (SNP) | VAF 57/255 reads (22%) | catalogued as rs1426266404; called by muse, mutect2, varscan2
- OR2L13 | c.535G>T p.D179Y | Missense Mutation (SNP) | VAF 384/564 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV63552858; called by muse, varscan2
- OSBPL7 | c.1865A>G p.N622S | Missense Mutation (SNP) | VAF 51/357 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.361); catalogued as COSV50111007; called by muse, mutect2, varscan2
- OTOF | c.4415C>A p.A1472D (on ENST00000272371 / NM_194248.3; = p.A705D on NM_004802.4) | Missense Mutation (SNP) | VAF 153/633 reads (24%) | SIFT tolerated (0.67); PolyPhen benign (0.129); catalogued as COSV55511216; called by muse, mutect2, varscan2
- OTOG | c.2066C>T p.P689L | Missense Mutation (SNP) | VAF 82/362 reads (23%) | SIFT tolerated (0.95); PolyPhen probably damaging (0.995); catalogued as rs1182393340, COSV68038832; called by muse, mutect2, varscan2
- OTOGL | c.6300G>C p.Q2100H (on ENST00000547103; = p.Q2091H on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 29/179 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.37); catalogued as rs1256176874; called by muse, mutect2, varscan2
- PAH | c.613G>T p.E205* | Nonsense Mutation (SNP) | VAF 241/483 reads (50%) | catalogued as CM068056; called by muse, mutect2, varscan2
- PC | c.1582G>A p.V528I | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs200433873, COSV58920866; called by muse, mutect2, varscan2
- PCSK7 | c.1198G>A p.E400K | Missense Mutation (SNP) | VAF 35/132 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.439); catalogued as rs751156091, COSV100309220; called by muse, mutect2, varscan2
- PIEZO2 | c.7016G>A p.R2339H | Missense Mutation (SNP) | VAF 17/126 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99555018; called by muse, mutect2, varscan2
- PLSCR5 | c.492C>A p.Y164* | Nonsense Mutation (SNP) | VAF 120/279 reads (43%) | catalogued as COSV99068681; called by muse, mutect2, varscan2
- PMS2 | c.13G>C p.E5Q | Missense Mutation (SNP) | VAF 113/1059 reads (11%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.368); catalogued as rs372539944, COSV56149941; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- POU6F2 | c.1829G>A p.R610Q | Missense Mutation (SNP) | VAF 99/2126 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs1310902537; called by muse, mutect2
- PPP6R3 | c.727G>C p.E243Q | Missense Mutation (SNP) | VAF 55/197 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV99678042; called by muse, mutect2, varscan2
- PRR14L | c.3653C>G p.S1218* | Nonsense Mutation (SNP) | VAF 91/430 reads (21%) | catalogued as COSV99043092; called by muse, mutect2, varscan2
- PTPRR | c.160C>G p.L54V | Missense Mutation (SNP) | VAF 230/581 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.978); catalogued as rs778886611; called by muse, mutect2, varscan2
- PTPRS | c.826G>A p.V276M | Missense Mutation (SNP) | VAF 28/129 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53639124; called by muse, mutect2, varscan2
- RAD23A | c.905G>C p.G302A | Missense Mutation (SNP) | VAF 25/169 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.172); catalogued as COSV100379708; called by muse, mutect2, varscan2
- RMDN2 | c.577G>C p.E193Q (on ENST00000354545 / NM_001322212.2; = p.E371Q on NM_144713.5) | Missense Mutation (SNP) | VAF 37/206 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.037); catalogued as rs1199130957, COSV52224941; called by muse, mutect2, varscan2
- RPGR | c.779-3C>T | Splice Region (SNP) | VAF 117/435 reads (27%) | catalogued as COSV58835319; called by muse, mutect2, varscan2
- RUNX1 | c.79G>T p.E27* (on ENST00000344691 / NM_001001890.3; = p.E54* on NM_001754.5) | Nonsense Mutation (SNP) | VAF 107/500 reads (21%) | catalogued as COSV55868660, COSV55892827; called by muse, mutect2, varscan2
- RWDD2B | c.375G>C p.L125F | Missense Mutation (SNP) | VAF 26/153 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV99725515; called by muse, mutect2, varscan2
- SEMA3D | c.1601G>A p.C534Y | Missense Mutation (SNP) | VAF 133/461 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99406200; called by muse, mutect2, varscan2
- SHANK1 | c.6254C>T p.P2085L | Missense Mutation (SNP) | VAF 39/103 reads (38%) | SIFT tolerated (0.34); PolyPhen benign (0.091); catalogued as rs924451909; called by muse, mutect2, varscan2
- SLC5A4 | c.1714G>A p.D572N | Missense Mutation (SNP) | VAF 84/535 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.082); catalogued as rs757754001; called by muse, mutect2, varscan2
- SMURF1 | c.1224C>G p.I408M | Missense Mutation (SNP) | VAF 107/671 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100742475; called by muse, mutect2, varscan2
- SP110 | c.1241del p.K414Rfs*12 | Frame Shift Del (DEL) | VAF 115/552 reads (21%) | catalogued as rs1559146826; called by mutect2, pindel, varscan2
- SPARC | c.601G>C p.E201Q | Missense Mutation (SNP) | VAF 33/120 reads (28%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.974); catalogued as COSV50560603; called by muse, mutect2, varscan2
- SPATA20 | c.2219C>T p.S740L (on ENST00000356488 / NM_001258372.1; = p.S756L on NM_022827.4) | Missense Mutation (SNP) | VAF 33/265 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0.005); catalogued as rs745451259; called by muse, mutect2, varscan2
- SPATA31D1 | c.3295G>A p.E1099K | Missense Mutation (SNP) | VAF 44/125 reads (35%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as rs569655832, COSV61193279; called by muse, mutect2, varscan2
- SPATC1 | c.1303C>T p.R435* | Nonsense Mutation (SNP) | VAF 13/44 reads (30%) | catalogued as rs782739842; called by muse, mutect2, varscan2
- SPOCD1 | c.1174G>T p.E392* | Nonsense Mutation (SNP) | VAF 30/45 reads (67%) | catalogued as COSV57094886; called by muse, mutect2, varscan2
- TAB2 | c.1034G>C p.G345A | Missense Mutation (SNP) | VAF 141/496 reads (28%) | SIFT tolerated (0.73); PolyPhen benign (0.003); catalogued as COSV53854952; called by muse, mutect2, varscan2
- TADA2A | c.367C>G p.L123V | Missense Mutation (SNP) | VAF 33/384 reads (9%) | SIFT tolerated (0.24); PolyPhen benign (0.015); catalogued as rs750812372; called by muse, mutect2
- TENM2 | c.8156G>A p.R2719K (on ENST00000518659 / NM_001122679.2; = p.R2480K on NM_001080428.3) | Missense Mutation (SNP) | VAF 65/561 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV101319322; called by muse, mutect2, varscan2
- TERT | c.2036C>T p.S679F | Missense Mutation (SNP) | VAF 23/353 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57211055; called by muse, mutect2
- TGIF2LX | c.199G>T p.D67Y | Missense Mutation (SNP) | VAF 112/1156 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.62); catalogued as COSV52215049; called by muse, mutect2
- TMEM200C | c.673G>A p.A225T | Missense Mutation (SNP) | VAF 43/134 reads (32%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.318); catalogued as rs1047939764, COSV67309908; called by muse, mutect2, varscan2
- TMPO | c.664-6G>C | Splice Region (SNP) | VAF 55/464 reads (12%) | catalogued as COSV58463017; called by muse, mutect2, varscan2
- TRAPPC10 | c.1597G>A p.G533R | Missense Mutation (SNP) | VAF 63/412 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.593); catalogued as rs200658810; called by muse, mutect2, varscan2
- TRIM41 | c.1676A>G p.Y559C | Missense Mutation (SNP) | VAF 607/1086 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs757149132; called by muse, mutect2, varscan2
- TRIO | c.2464A>T p.T822S | Missense Mutation (SNP) | VAF 378/461 reads (82%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.956); catalogued as COSV100711249; called by muse, mutect2, varscan2
- TRPM5 | c.2371G>A p.E791K | Missense Mutation (SNP) | VAF 56/227 reads (25%) | SIFT tolerated (0.53); PolyPhen benign (0.046); catalogued as rs538398031, COSV99329310; called by muse, mutect2, varscan2
- TSNAXIP1 | c.503C>T p.S168L | Missense Mutation (SNP) | VAF 36/144 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54647995; called by muse, mutect2
- TTN | c.89573G>A p.R29858K (on ENST00000591111; = p.R22434K on NM_003319.4) | Missense Mutation (SNP) | VAF 28/123 reads (23%) | PolyPhen probably damaging (0.987); catalogued as COSV59901427; called by muse, varscan2
- ULK1 | c.1519C>G p.Q507E | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT tolerated (0.37); PolyPhen benign (0.139); catalogued as COSV58855959; called by muse, mutect2, varscan2
- VPS13B | c.8637G>T p.Q2879H | Missense Mutation (SNP) | VAF 216/341 reads (63%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs771886409, COSV62147654; called by muse, mutect2, varscan2
- XIRP1 | c.3074C>G p.S1025C | Missense Mutation (SNP) | VAF 145/691 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.088); catalogued as COSV61137315; called by muse, mutect2, varscan2
- ZDBF2 | c.6745C>G p.L2249V | Missense Mutation (SNP) | VAF 92/217 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.168); catalogued as rs758381329; called by muse, mutect2, varscan2
- ZNF256 | c.91C>A p.L31I | Missense Mutation (SNP) | VAF 64/360 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.755); catalogued as COSV56598521; called by muse, mutect2, varscan2
- ZNF775 | c.70G>C p.E24Q | Missense Mutation (SNP) | VAF 89/780 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.638); catalogued as rs750020032; called by muse, mutect2, varscan2
- ABCA2 | c.5260G>T p.V1754L (on ENST00000614293; = p.V1724L on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/141 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.22); called by muse, mutect2, varscan2
- ACO2 | c.136G>A p.D46N | Missense Mutation (SNP) | VAF 39/271 reads (14%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADAM2 | c.662T>C p.I221T | Missense Mutation (SNP) | VAF 72/101 reads (71%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.579); called by muse, mutect2, varscan2
- AGAP1 | c.1783G>T p.E595* (on ENST00000304032 / NM_001037131.3; = p.E542* on NM_014914.5) | Nonsense Mutation (SNP) | VAF 92/200 reads (46%) | called by muse, mutect2, varscan2
- AK9 | c.4521G>C p.M1507I | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- ALDH1A2 | c.1174C>G p.L392V | Missense Mutation (SNP) | VAF 235/398 reads (59%) | SIFT tolerated (0.85); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- ALG13 | c.2966G>A p.G989E | Missense Mutation (SNP) | VAF 37/168 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ANK2 | c.8524G>A p.E2842K | Missense Mutation (SNP) | VAF 166/772 reads (22%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- ARHGEF17 | c.326C>T p.A109V | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARL6IP1 | c.334C>G p.L112V | Missense Mutation (SNP) | VAF 26/406 reads (6%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.547); called by muse, mutect2
- ARMCX5 | c.519G>C p.W173C | Missense Mutation (SNP) | VAF 37/450 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.091); called by muse, mutect2
- ARSH | c.152C>A p.A51D | Missense Mutation (SNP) | VAF 16/192 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- ASTN2 | c.1283T>A p.L428Q (on ENST00000313400 / NM_001365069.1; = p.L377Q on NM_014010.5) | Missense Mutation (SNP) | VAF 33/92 reads (36%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- ASXL3 | c.5197G>T p.A1733S | Missense Mutation (SNP) | VAF 219/437 reads (50%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ATP11C | c.934C>G p.L312V | Missense Mutation (SNP) | VAF 73/357 reads (20%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- AVPR1A | c.1183A>C p.T395P | Missense Mutation (SNP) | VAF 123/413 reads (30%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- B3GALNT2 | c.1309C>G p.Q437E | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- B3GNT5 | c.844G>A p.D282N | Missense Mutation (SNP) | VAF 53/259 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BICC1 | c.1855G>T p.E619* | Nonsense Mutation (SNP) | VAF 59/157 reads (38%) | called by muse, mutect2, varscan2
- C10orf71 | c.3877C>A p.Q1293K | Missense Mutation (SNP) | VAF 64/158 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.766); called by muse, mutect2, varscan2
- C18orf54 | c.511C>T p.Q171* | Nonsense Mutation (SNP) | VAF 84/318 reads (26%) | called by muse, mutect2, varscan2
- CACNG3 | c.927C>A p.N309K | Missense Mutation (SNP) | VAF 50/138 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.787); called by muse, varscan2
- CAMSAP2 | c.3904G>A p.V1302I (on ENST00000236925 / NM_001297707.2; = p.V1291I on NM_203459.3) | Missense Mutation (SNP) | VAF 68/209 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2, varscan2
- CAPN7 | c.1329G>C p.M443I | Missense Mutation (SNP) | VAF 42/188 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.007); called by muse, varscan2
- CCDC58 | c.97G>A p.E33K | Missense Mutation (SNP) | VAF 61/248 reads (25%) | SIFT tolerated (0.7); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CDKL2 | c.914A>T p.Q305L | Missense Mutation (SNP) | VAF 113/244 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CDX1 | c.110C>T p.P37L | Missense Mutation (SNP) | VAF 26/209 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- CEP170 | c.2020G>C p.D674H | Missense Mutation (SNP) | VAF 48/454 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CEP192 | c.316G>C p.V106L | Missense Mutation (SNP) | VAF 67/241 reads (28%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2, varscan2
- CFAP65 | c.436G>T p.E146* (on ENST00000341552 / NM_194302.4; = p.E81* on NM_152389.4) | Nonsense Mutation (SNP) | VAF 211/422 reads (50%) | called by muse, mutect2, varscan2
- CHMP4B | c.88C>T p.R30W | Missense Mutation (SNP) | VAF 181/465 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CNTNAP4 | c.2174G>C p.G725A | Missense Mutation (SNP) | VAF 56/211 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- CSNK2A3 | c.745C>G p.L249V | Missense Mutation (SNP) | VAF 230/1029 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.582); called by muse, mutect2, varscan2
- CTSW | c.1092G>C p.Q364H | Missense Mutation (SNP) | VAF 33/171 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CYP2A7P1 | n.180G>A | Splice Region (SNP) | VAF 50/177 reads (28%) | called by muse, mutect2, varscan2
- CYP2W1 | c.464C>T p.S155F | Missense Mutation (SNP) | VAF 35/304 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- CYP7B1 | c.210G>A p.M70I | Missense Mutation (SNP) | VAF 106/346 reads (31%) | SIFT tolerated (0.25); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- DDI1 | c.704C>A p.P235H | Missense Mutation (SNP) | VAF 278/594 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DGKK | c.1370C>T p.S457L | Missense Mutation (SNP) | VAF 100/416 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- DNHD1 | c.4334C>T p.P1445L | Missense Mutation (SNP) | VAF 121/636 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- DNMBP | c.4282G>A p.E1428K | Missense Mutation (SNP) | VAF 138/579 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DOCK10 | c.246A>G p.A82= | Splice Region (SNP) | VAF 56/230 reads (24%) | called by muse, mutect2, varscan2
- DST | c.17572G>T p.A5858S (on ENST00000361203 / NM_001374722.1; = p.A3555S on NM_015548.5) | Missense Mutation (SNP) | VAF 144/230 reads (63%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- EIF2B5 | c.1660C>G p.Q554E (on ENST00000647909; = p.Q546E on NM_003907.3) | Missense Mutation (SNP) | VAF 83/361 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- EMX1 | c.605C>T p.S202L | Missense Mutation (SNP) | VAF 88/398 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); called by muse, mutect2, varscan2
- EPX | c.1289C>T p.T430I | Missense Mutation (SNP) | VAF 133/1334 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2
- ESYT1 | c.2539G>C p.E847Q | Missense Mutation (SNP) | VAF 72/394 reads (18%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.995); called by muse, mutect2
- ESYT1 | c.2575G>A p.E859K | Missense Mutation (SNP) | VAF 54/302 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); called by muse, mutect2
- FAM221B | c.806C>G p.S269C | Missense Mutation (SNP) | VAF 118/397 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- FLNA | c.4148C>A p.A1383D | Missense Mutation (SNP) | VAF 52/586 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- FMO4 | c.1198C>G p.P400A | Missense Mutation (SNP) | VAF 89/283 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.603); called by muse, mutect2, varscan2
- FNDC7 | c.1176G>T p.W392C | Missense Mutation (SNP) | VAF 74/209 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GDAP2 | c.103G>C p.E35Q | Missense Mutation (SNP) | VAF 55/150 reads (37%) | SIFT tolerated (0.5); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- GFRA2 | c.178C>G p.L60V | Missense Mutation (SNP) | VAF 116/410 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.622); called by muse, mutect2, varscan2
- GLB1L2 | c.200C>G p.S67C | Missense Mutation (SNP) | VAF 70/317 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- GLG1 | c.3388G>T p.G1130C | Missense Mutation (SNP) | VAF 94/131 reads (72%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- GOLGB1 | c.421G>T p.E141* | Nonsense Mutation (SNP) | VAF 61/225 reads (27%) | called by muse, mutect2, varscan2
- GPR152 | c.1201G>C p.D401H | Missense Mutation (SNP) | VAF 113/595 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.206); called by muse, mutect2, varscan2
- GRIA3 | c.1570C>A p.P524T | Missense Mutation (SNP) | VAF 20/220 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2
- GRK3 | c.114-7_134del p.X38_splice | Splice Site (DEL) | VAF 16/188 reads (9%) | called by mutect2, pindel
- HAL | c.1888G>C p.E630Q | Missense Mutation (SNP) | VAF 96/544 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.82); called by muse, mutect2, varscan2
- HECTD4 | c.568G>T p.D190Y | Missense Mutation (SNP) | VAF 107/541 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HERPUD1 | c.16G>T p.E6* | Nonsense Mutation (SNP) | VAF 131/418 reads (31%) | called by muse, mutect2, varscan2
- HMCN2 | c.2334G>T p.Q778H | Missense Mutation (SNP) | VAF 28/95 reads (29%) | SIFT tolerated (0.58); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- HMCN2 | c.10594C>A p.Q3532K | Missense Mutation (SNP) | VAF 70/198 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- HNRNPA1L2 | c.390A>T p.K130N | Missense Mutation (SNP) | VAF 134/459 reads (29%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- IFNAR1 | c.58G>T p.V20L | Missense Mutation (SNP) | VAF 159/479 reads (33%) | SIFT tolerated (0.24); PolyPhen benign (0.117); called by muse, mutect2, varscan2
- IRAK1 | c.160A>T p.T54S | Missense Mutation (SNP) | VAF 13/148 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); called by muse, mutect2
- IRF6 | c.736C>T p.P246S | Missense Mutation (SNP) | VAF 58/181 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- JMY | c.2045G>C p.R682T | Missense Mutation (SNP) | VAF 32/124 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- KIF1A | c.939G>T p.W313C | Missense Mutation (SNP) | VAF 59/157 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KIR3DL3 | c.320C>G p.S107W | Missense Mutation (SNP) | VAF 96/242 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- KLHL34 | c.418C>T p.R140C | Missense Mutation (SNP) | VAF 11/127 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); called by muse, mutect2
- KRTAP19-6 | c.133C>A p.R45S | Missense Mutation (SNP) | VAF 159/454 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.136); called by muse, mutect2, varscan2
- KRTAP9-1 | c.12C>A p.C4* | Nonsense Mutation (SNP) | VAF 128/256 reads (50%) | called by muse, mutect2, varscan2
- LAMA5 | c.3085G>A p.E1029K | Missense Mutation (SNP) | VAF 42/341 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.626); called by muse, mutect2, varscan2
- LCAT | c.1015_1030del p.Y339Pfs*66 | Frame Shift Del (DEL) | VAF 74/521 reads (14%) | called by mutect2, pindel, varscan2
- LIX1 | c.82+1G>A p.X28_splice | Splice Site (SNP) | VAF 46/356 reads (13%) | called by muse, varscan2
- LPO | c.1346G>A p.S449N | Missense Mutation (SNP) | VAF 225/699 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, varscan2
- LRIG3 | c.1245-1G>A p.X415_splice | Splice Site (SNP) | VAF 14/69 reads (20%) | called by muse, mutect2, varscan2
- LRP2 | c.13692G>C p.E4564D | Missense Mutation (SNP) | VAF 99/452 reads (22%) | SIFT tolerated (0.76); PolyPhen benign (0); called by muse, mutect2, varscan2
- LRRC70 | c.1774C>G p.L592V | Missense Mutation (SNP) | VAF 72/242 reads (30%) | SIFT tolerated (0.42); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- LRRTM3 | c.1503C>A p.C501* | Nonsense Mutation (SNP) | VAF 52/220 reads (24%) | called by muse, varscan2
- LTV1 | c.1073C>G p.S358* | Nonsense Mutation (SNP) | VAF 41/154 reads (27%) | called by muse, mutect2, varscan2
- LUZP1 | c.646C>T p.Q216* | Nonsense Mutation (SNP) | VAF 120/283 reads (42%) | called by muse, mutect2, varscan2
- MACF1 | c.18636+1G>T p.X6212_splice (on ENST00000372915; = p.X4257_splice on NM_012090.5) | Splice Site (SNP) | VAF 14/56 reads (25%) | called by muse, mutect2, varscan2
- MACF1 | c.20710G>C p.E6904Q (on ENST00000372915; = p.E4949Q on NM_012090.5) | Missense Mutation (SNP) | VAF 56/275 reads (20%) | called by muse, mutect2, varscan2
- MAGEB6B | c.751G>A p.E251K | Missense Mutation (SNP) | VAF 42/362 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- MAMDC4 | c.3322-1G>C p.X1108_splice (on ENST00000445819; = p.X1029_splice on NM_206920.3) | Splice Site (SNP) | VAF 28/78 reads (36%) | called by muse, mutect2, varscan2
- MDN1 | c.2473C>T p.Q825* | Nonsense Mutation (SNP) | VAF 59/162 reads (36%) | called by muse, mutect2, varscan2
- MPI | c.562C>G p.Q188E | Missense Mutation (SNP) | VAF 80/242 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- MROH5 | c.1819C>A p.H607N | Missense Mutation (SNP) | VAF 154/433 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- MRPS26 | c.240G>T p.R80S | Missense Mutation (SNP) | VAF 55/235 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- MXRA5 | c.1825C>A p.L609I | Missense Mutation (SNP) | VAF 13/109 reads (12%) | SIFT tolerated (0.35); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- MYBL2 | c.2059C>A p.R687S | Missense Mutation (SNP) | VAF 249/332 reads (75%) | SIFT tolerated (0.7); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- MYRIP | c.2497T>A p.S833T | Missense Mutation (SNP) | VAF 134/322 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.138); called by muse, varscan2
- NDUFAF1 | c.456G>C p.L152F | Missense Mutation (SNP) | VAF 97/342 reads (28%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.803); called by muse, varscan2
- NDUFAF1 | c.355G>C p.E119Q | Missense Mutation (SNP) | VAF 57/168 reads (34%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.91); called by muse, varscan2
- NELL1 | c.1280G>T p.G427V | Missense Mutation (SNP) | VAF 56/250 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.728); called by muse, mutect2, varscan2
- NR5A2 | c.1450T>C p.Y484H (on ENST00000367362 / NM_205860.3; = p.Y438H on NM_003822.5) | Missense Mutation (SNP) | VAF 25/173 reads (14%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- NR6A1 | c.739G>T p.D247Y (on ENST00000487099 / NM_033334.4; = p.D242Y on NM_001489.5) | Missense Mutation (SNP) | VAF 55/190 reads (29%) | SIFT tolerated (0.24); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- OR13G1 | c.697A>G p.K233E | Missense Mutation (SNP) | VAF 72/421 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.734); called by muse, mutect2, varscan2
- OR4D2 | c.586G>A p.E196K | Missense Mutation (SNP) | VAF 668/1361 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR4M1 | c.392A>T p.H131L | Missense Mutation (SNP) | VAF 87/577 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.218); called by muse, mutect2, varscan2
- OR56A3 | c.703G>T p.E235* | Nonsense Mutation (SNP) | VAF 104/345 reads (30%) | called by muse, mutect2, varscan2
- OR5K3 | c.495G>T p.R165S | Missense Mutation (SNP) | VAF 66/356 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- OSBPL1A | c.1911A>T p.R637= (on ENST00000319481 / NM_080597.4; = p.R124= on NM_018030.4) | Splice Region (SNP) | VAF 14/66 reads (21%) | called by muse, mutect2, varscan2
- PABPC1L | c.904G>A p.D302N | Missense Mutation (SNP) | VAF 266/353 reads (75%) | SIFT deleterious (0.01); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- PARP1 | c.1600G>T p.D534Y | Missense Mutation (SNP) | VAF 180/677 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- PASD1 | c.718G>A p.D240N | Missense Mutation (SNP) | VAF 45/240 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- PCDHA3 | c.1895G>A p.S632N | Missense Mutation (SNP) | VAF 343/435 reads (79%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.827); called by muse, mutect2, varscan2
- PEG10 | c.493G>C p.E165Q (on ENST00000482108 / NM_001040152.2; = p.E199Q on NM_015068.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 181/1040 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.289); called by muse, mutect2, varscan2
- PHF20L1 | c.2106G>T p.L702F | Missense Mutation (SNP) | VAF 304/577 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- PHKA2 | c.845A>T p.E282V | Missense Mutation (SNP) | VAF 317/524 reads (60%) | SIFT deleterious (0.05); PolyPhen benign (0.155); called by muse, mutect2, varscan2
- PIK3C2A | c.3699C>G p.I1233M | Missense Mutation (SNP) | VAF 44/229 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PKNOX2 | c.17C>T p.S6F | Missense Mutation (SNP) | VAF 110/478 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- PLA2G4E | c.196C>T p.P66S | Missense Mutation (SNP) | VAF 86/269 reads (32%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.857); called by muse, mutect2, varscan2
- PLD2 | c.2572G>C p.E858Q | Missense Mutation (SNP) | VAF 35/168 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- PLXNA4 | c.1878G>C p.E626D | Missense Mutation (SNP) | VAF 105/377 reads (28%) | SIFT tolerated (0.7); PolyPhen benign (0); called by muse, mutect2, varscan2
- POLR3D | c.554C>G p.S185* | Nonsense Mutation (SNP) | VAF 69/268 reads (26%) | called by muse, mutect2, varscan2
- PPFIA4 | c.1124T>G p.I375S | Missense Mutation (SNP) | VAF 46/202 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- PRKCG | c.1326G>C p.L442F | Missense Mutation (SNP) | VAF 188/1089 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PROM1 | c.795G>C p.E265D | Missense Mutation (SNP) | VAF 53/165 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.101); called by muse, mutect2
- PRSS36 | c.1295C>T p.P432L | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); called by muse, mutect2, varscan2
- PSMD12 | c.63C>A p.S21R | Missense Mutation (SNP) | VAF 70/221 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); called by muse, mutect2, varscan2
- PTBP2 | c.983C>G p.A328G (on ENST00000426398 / NM_001300986.2; = p.A320G on NM_021190.4) | Missense Mutation (SNP) | VAF 71/174 reads (41%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- PTPRR | c.159C>A p.S53R | Missense Mutation (SNP) | VAF 226/570 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- QSER1 | c.3108G>A p.M1036I (on ENST00000399302; = p.M1165I on NM_001076786.3) | Missense Mutation (SNP) | VAF 37/177 reads (21%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, mutect2, varscan2
- QTRT1 | c.481G>T p.V161L | Missense Mutation (SNP) | VAF 145/388 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RBM41 | c.61G>C p.E21Q | Missense Mutation (SNP) | VAF 81/419 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- RDH16 | c.879del p.M294* | Frame Shift Del (DEL) | VAF 95/476 reads (20%) | called by mutect2, pindel, varscan2
- RHOBTB1 | c.301G>A p.D101N | Missense Mutation (SNP) | VAF 42/106 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ROBO2 | c.4114G>A p.G1372R | Missense Mutation (SNP) | VAF 112/463 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- RPA1 | c.1727_1746+28del p.X576_splice | Splice Site (DEL) | VAF 54/173 reads (31%) | called by mutect2, pindel
- RPA2 | c.481G>C p.E161Q | Missense Mutation (SNP) | VAF 47/300 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, varscan2
- RRN3 | c.222G>C p.L74F | Missense Mutation (SNP) | VAF 12/124 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- SARDH | c.1451G>C p.R484T | Missense Mutation (SNP) | VAF 27/107 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.132); called by muse, mutect2, varscan2
- SBNO2 | c.3166A>G p.K1056E | Missense Mutation (SNP) | VAF 141/390 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.242); called by muse, mutect2, varscan2
- SLC22A2 | c.1143C>G p.F381L | Missense Mutation (SNP) | VAF 101/316 reads (32%) | SIFT tolerated (0.7); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- SLC26A7 | c.796-2A>T p.X266_splice | Splice Site (SNP) | VAF 88/137 reads (64%) | called by muse, mutect2, varscan2
- SLC37A1 | c.1081G>C p.D361H | Missense Mutation (SNP) | VAF 83/446 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.25); called by muse, mutect2, varscan2
- SLC43A3 | c.866dup p.Q290Tfs*54 | Frame Shift Ins (INS) | VAF 78/427 reads (18%) | called by mutect2, pindel, varscan2
- SLC6A16 | c.882C>G p.I294M | Missense Mutation (SNP) | VAF 41/231 reads (18%) | SIFT tolerated (0.88); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- SLC6A9 | c.943-2A>T p.X315_splice (on ENST00000360584 / NM_201649.4; = p.X261_splice on NM_006934.4 and 2 other RefSeq transcripts) | Splice Site (SNP) | VAF 106/214 reads (50%) | called by muse, mutect2, varscan2
- SLITRK4 | c.1946C>T p.P649L | Missense Mutation (SNP) | VAF 30/336 reads (9%) | SIFT tolerated (0.31); PolyPhen benign (0.269); called by muse, mutect2
- SMYD3 | c.1122G>A p.M374I (on ENST00000490107 / NM_001375962.1; = p.M315I on NM_022743.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/289 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.318); called by muse, mutect2, varscan2
- SNAI2 | c.554G>A p.C185Y | Missense Mutation (SNP) | VAF 84/236 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SNX30 | c.381T>A p.Y127* | Nonsense Mutation (SNP) | VAF 60/174 reads (34%) | called by muse, varscan2
- SOS2 | c.3136G>T p.G1046C | Missense Mutation (SNP) | VAF 158/279 reads (57%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.502); called by muse, mutect2, varscan2
- SOX11 | c.717C>G p.I239M | Missense Mutation (SNP) | VAF 109/490 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.081); called by muse, varscan2
- SPATA31A1 | c.3493G>T p.G1165* | Nonsense Mutation (SNP) | VAF 276/841 reads (33%) | called by muse, mutect2, varscan2
- SPATA31A1 | c.3721G>T p.A1241S | Missense Mutation (SNP) | VAF 172/740 reads (23%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- SPATS2 | c.598C>T p.Q200* | Nonsense Mutation (SNP) | VAF 59/200 reads (30%) | called by muse, mutect2, varscan2
- SPHK2 | c.1354G>C p.E452Q | Missense Mutation (SNP) | VAF 68/338 reads (20%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.655); called by muse, mutect2, varscan2
- SRRM1 | c.2054C>T p.S685L | Missense Mutation (SNP) | VAF 133/977 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- SSC5D | c.73G>T p.G25C | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SUV39H1 | c.393G>A p.W131* | Nonsense Mutation (SNP) | VAF 49/407 reads (12%) | called by muse, mutect2, varscan2
- TAS2R16 | c.751C>A p.L251I | Missense Mutation (SNP) | VAF 126/292 reads (43%) | SIFT tolerated (0.69); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- TBCD | c.1871C>T p.A624V | Missense Mutation (SNP) | VAF 123/364 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); called by mutect2, varscan2
- TBCE | c.1228A>C p.K410Q (on ENST00000366601; = p.K473Q on NM_003193.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 173/475 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- TFAP2D | c.740C>T p.S247L | Missense Mutation (SNP) | VAF 140/200 reads (70%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, varscan2
- THEMIS2 | c.1504C>T p.P502S | Missense Mutation (SNP) | VAF 242/560 reads (43%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- TIAM1 | c.214G>T p.G72C | Missense Mutation (SNP) | VAF 172/439 reads (39%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- TMEM184B | c.28C>A p.P10T | Missense Mutation (SNP) | VAF 82/188 reads (44%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- TMEM74 | c.149C>A p.P50Q | Missense Mutation (SNP) | VAF 167/690 reads (24%) | SIFT tolerated (0.67); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- TRBV2 | c.171C>G p.I57M | Missense Mutation (SNP) | VAF 95/432 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.27); called by muse, varscan2
- TRBV4-2 | c.35G>C p.C12S | Missense Mutation (SNP) | VAF 182/421 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.886); called by muse, mutect2, varscan2
- TRIM9 | c.2012C>G p.A671G | Missense Mutation (SNP) | VAF 114/727 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- TRRAP | c.2653G>A p.D885N | Missense Mutation (SNP) | VAF 65/605 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- TRRAP | c.10429G>A p.E3477K (on ENST00000359863 / NM_001244580.1; = p.E3448K on NM_003496.3) | Missense Mutation (SNP) | VAF 89/789 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- TSPAN11 | c.729C>G p.C243W | Missense Mutation (SNP) | VAF 66/425 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.547); called by muse, mutect2, varscan2
- UGT8 | c.922C>G p.L308V | Missense Mutation (SNP) | VAF 89/353 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.45); called by muse, mutect2, varscan2
- UMODL1 | c.3370C>G p.P1124A (on ENST00000408910 / NM_001004416.2; = p.P1252A on NM_173568.3) | Missense Mutation (SNP) | VAF 182/1098 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- URB2 | c.2870G>T p.S957I | Missense Mutation (SNP) | VAF 93/392 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.23); called by muse, mutect2, varscan2
- USH1C | c.605C>A p.P202H | Missense Mutation (SNP) | VAF 325/774 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0.161); called by muse, mutect2, varscan2
- UTP25 | c.541T>A p.S181T | Missense Mutation (SNP) | VAF 26/98 reads (27%) | SIFT tolerated (0.42); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- UTP25 | c.542C>G p.S181C | Missense Mutation (SNP) | VAF 23/94 reads (24%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- WASHC2A | c.253G>A p.D85N | Missense Mutation (SNP) | VAF 85/237 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.529); called by muse, mutect2, varscan2
- WDR33 | c.3001G>A p.D1001N | Missense Mutation (SNP) | VAF 46/193 reads (24%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.239); called by muse, mutect2, varscan2
- WDR88 | c.121G>A p.A41T | Missense Mutation (SNP) | VAF 83/394 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- XRCC1 | c.1427-1G>C p.X476_splice | Splice Site (SNP) | VAF 72/407 reads (18%) | called by muse, mutect2, varscan2
- YJEFN3 | c.292C>A p.H98N | Missense Mutation (SNP) | VAF 50/241 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.529); called by muse, mutect2, varscan2
- ZBED2 | c.544G>C p.E182Q | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.636); called by muse, mutect2, varscan2
- ZCWPW2 | c.412C>G p.H138D | Missense Mutation (SNP) | VAF 95/475 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- ZFPM2 | c.3388A>T p.N1130Y | Missense Mutation (SNP) | VAF 95/410 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZFYVE26 | c.5716G>C p.D1906H | Missense Mutation (SNP) | VAF 144/700 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- ZMYM6 | c.1634G>T p.C545F | Missense Mutation (SNP) | VAF 70/179 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF154 | c.899C>A p.P300H | Missense Mutation (SNP) | VAF 198/480 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- ZNF443 | c.262C>A p.Q88K | Missense Mutation (SNP) | VAF 28/147 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- ZNF473 | c.1884C>G p.I628M | Missense Mutation (SNP) | VAF 81/450 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- ZNF496 | c.1383G>T p.K461N | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- ZNF577 | c.1051G>T p.E351* | Nonsense Mutation (SNP) | VAF 172/478 reads (36%) | called by muse, mutect2, varscan2
- ZNF711 | c.1805C>T p.S602L | Missense Mutation (SNP) | VAF 179/666 reads (27%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.68); called by muse, mutect2, varscan2
- ZNF726 | c.1705G>T p.E569* | Nonsense Mutation (SNP) | VAF 110/293 reads (38%) | called by muse, mutect2, varscan2
- ZNF729 | c.162G>T p.M54I | Missense Mutation (SNP) | VAF 44/86 reads (51%) | SIFT tolerated (0.87); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF780B | c.1978C>G p.Q660E | Missense Mutation (SNP) | VAF 33/172 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- ABCA2 | c.5259G>T p.A1753= (on ENST00000614293; = p.A1723= on NM_001606.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 37/147 reads (25%) | catalogued as rs1002248853; called by muse, mutect2, varscan2
- AC132217.2 | c.51C>G p.L17= | Silent (SNP) | VAF 67/307 reads (22%) | called by muse, mutect2, varscan2
- ADAMTS8 | c.2205G>A p.L735= | Silent (SNP) | VAF 70/316 reads (22%) | catalogued as rs879170614; called by muse, mutect2, varscan2
- AP3S2 | c.213C>G p.L71= | Silent (SNP) | VAF 60/228 reads (26%) | called by muse, mutect2, varscan2
- AP4E1 | c.1992C>G p.L664= | Silent (SNP) | VAF 80/262 reads (31%) | called by muse, mutect2, varscan2
- ASH1L | c.1902T>C p.N634= | Silent (SNP) | VAF 45/334 reads (13%) | catalogued as rs760194400; called by muse, mutect2, varscan2
- ATP6V0C | c.405C>G p.L135= | Silent (SNP) | VAF 15/126 reads (12%) | called by muse, mutect2, varscan2
- ATP8A2 | c.568C>T p.L190= | Silent (SNP) | VAF 37/119 reads (31%) | catalogued as rs756492691; called by muse, mutect2, varscan2
- ATRIP | c.237G>T p.R79= | Silent (SNP) | VAF 21/75 reads (28%) | called by muse, mutect2, varscan2
- B3GNT3 | c.126G>T p.A42= | Silent (SNP) | VAF 84/289 reads (29%) | catalogued as COSV59437768; called by muse, mutect2, varscan2
- BRINP2 | c.1293C>T p.T431= | Silent (SNP) | VAF 145/313 reads (46%) | called by muse, mutect2, varscan2
- C1QL3 | c.51C>T p.G17= | Silent (SNP) | VAF 112/366 reads (31%) | called by muse, mutect2, varscan2
- C2orf16 | c.1863C>A p.A621= | Silent (SNP) | VAF 33/168 reads (20%) | called by muse, mutect2, varscan2
- C5 | c.1089G>A p.L363= | Silent (SNP) | VAF 146/503 reads (29%) | called by muse, mutect2, varscan2
- C9 | c.1335C>A p.L445= | Silent (SNP) | VAF 456/574 reads (79%) | called by muse, mutect2, varscan2
- CCDC60 | c.1488G>A p.L496= | Silent (SNP) | VAF 54/273 reads (20%) | called by muse, mutect2, varscan2
- CD27 | c.549C>A p.S183= | Silent (SNP) | VAF 100/369 reads (27%) | catalogued as rs1172834306; called by muse, mutect2, varscan2
- CFAP47 | c.2097G>T p.A699= | Silent (SNP) | VAF 21/218 reads (10%) | catalogued as rs778565336, COSV52880140; called by muse, mutect2, varscan2
- CHAF1A | c.1743C>T p.I581= | Silent (SNP) | VAF 61/365 reads (17%) | catalogued as rs888321623, COSV100011393; called by muse, mutect2, varscan2
- CHD5 | c.2676C>T p.F892= | Silent (SNP) | VAF 11/251 reads (4%) | called by muse, mutect2
- CLCN5 | c.1089G>T p.V363= | Silent (SNP) | VAF 121/180 reads (67%) | called by muse, mutect2, varscan2
- COASY | c.1413C>A p.A471= | Silent (SNP) | VAF 110/637 reads (17%) | called by muse, mutect2, varscan2
- CUL4A | c.1146G>A p.K382= (on ENST00000375440 / NM_001008895.4; = p.K282= on NM_003589.3) | Silent (SNP) | VAF 67/273 reads (25%) | catalogued as rs971211908, COSV58376574; called by muse, mutect2, varscan2
- DEAF1 | c.489G>C p.L163= | Silent (SNP) | VAF 57/205 reads (28%) | catalogued as COSV58608667; called by muse, mutect2, varscan2
- DNAH5 | c.7587C>T p.F2529= | Silent (SNP) | VAF 345/570 reads (61%) | catalogued as rs1486190432, COSV99455329; called by muse, mutect2, varscan2
- DOCK2 | c.2388G>A p.L796= | Silent (SNP) | VAF 49/326 reads (15%) | called by muse, mutect2, varscan2
- EGFR | c.147C>T p.L49= | Silent (SNP) | VAF 115/1116 reads (10%) | called by muse, mutect2, varscan2
- EPG5 | c.7380G>A p.E2460= | Silent (SNP) | VAF 86/380 reads (23%) | catalogued as COSV56349358; called by muse, mutect2, varscan2
- EPHX2 | c.744C>A p.V248= | Silent (SNP) | VAF 83/240 reads (35%) | catalogued as COSV66845599; called by muse, mutect2, varscan2
- ERBIN | c.372A>G p.V124= | Silent (SNP) | VAF 71/112 reads (63%) | called by muse, mutect2, varscan2
- FAM120C | c.2232C>A p.A744= | Silent (SNP) | VAF 33/281 reads (12%) | catalogued as COSV100070527; called by muse, mutect2, varscan2
- FAM160A1 | c.924C>T p.V308= | Silent (SNP) | VAF 114/515 reads (22%) | called by muse, mutect2, varscan2
- FLG | c.4284T>C p.R1428= | Silent (SNP) | VAF 202/1227 reads (16%) | called by muse, mutect2, varscan2
- FLVCR1 | c.999T>G p.P333= | Silent (SNP) | VAF 75/257 reads (29%) | called by muse, mutect2, varscan2
- GIPR | c.177C>T p.L59= | Silent (SNP) | VAF 36/626 reads (6%) | catalogued as COSV54423208, COSV54423522; called by muse, mutect2
- GP5 | c.636G>T p.G212= | Silent (SNP) | VAF 126/525 reads (24%) | called by muse, mutect2, varscan2
- GPR152 | c.630C>T p.V210= | Silent (SNP) | VAF 88/212 reads (42%) | called by muse, mutect2, varscan2
- HECW1 | c.543C>T p.N181= | Silent (SNP) | VAF 107/205 reads (52%) | catalogued as rs764819634; called by muse, mutect2, varscan2
- HHLA1 | c.1500G>A p.L500= | Silent (SNP) | VAF 70/420 reads (17%) | catalogued as rs150159765; called by muse, mutect2, varscan2
- HLA-DOA | c.681C>T p.I227= | Silent (SNP) | VAF 84/256 reads (33%) | catalogued as rs762314322, COSV57714179, COSV57715250; called by muse, mutect2, varscan2
- IGHE | c.1101G>A p.P367= | Silent (SNP) | VAF 101/566 reads (18%) | catalogued as rs781808172; called by muse, mutect2, varscan2
- IGKV6D-21 | c.219C>G p.S73= | Silent (SNP) | VAF 130/645 reads (20%) | called by muse, mutect2, varscan2
- IKZF3 | c.1428C>T p.F476= | Silent (SNP) | VAF 59/389 reads (15%) | called by muse, mutect2, varscan2
- INSYN1 | c.150G>C p.L50= | Silent (SNP) | VAF 54/200 reads (27%) | called by muse, mutect2, varscan2
- IRS4 | c.3450C>A p.A1150= | Silent (SNP) | VAF 33/50 reads (66%) | catalogued as COSV64532512; called by muse, mutect2, varscan2
- IRS4 | c.1518C>A p.G506= | Silent (SNP) | VAF 259/1294 reads (20%) | called by muse, mutect2, varscan2
- ITIH3 | c.480G>C p.L160= | Silent (SNP) | VAF 83/417 reads (20%) | called by muse, mutect2, varscan2
- KAT6A | c.990C>T p.R330= | Silent (SNP) | VAF 87/152 reads (57%) | called by muse, mutect2, varscan2
- KCNH3 | c.1803C>A p.A601= | Silent (SNP) | VAF 132/271 reads (49%) | called by muse, mutect2, varscan2
- KCNJ10 | c.408C>A p.I136= | Silent (SNP) | VAF 39/56 reads (70%) | catalogued as rs762063217, COSV63634610; called by muse, varscan2
- KDM2B | c.1527C>T p.L509= | Silent (SNP) | VAF 92/635 reads (14%) | catalogued as COSV100997470, COSV65643349; called by muse, mutect2, varscan2
- KIF22 | c.810C>G p.L270= | Silent (SNP) | VAF 158/801 reads (20%) | called by muse, mutect2, varscan2
- KRTAP27-1 | c.63C>T p.I21= | Silent (SNP) | VAF 61/267 reads (23%) | catalogued as rs1568823271; called by muse, mutect2, varscan2
- LAMA1 | c.2565G>T p.V855= | Silent (SNP) | VAF 296/600 reads (49%) | called by muse, mutect2, varscan2
- LAMB4 | c.841C>A p.R281= | Silent (SNP) | VAF 191/272 reads (70%) | catalogued as rs751482652, COSV104391500, COSV52715777; called by muse, mutect2, varscan2
- LETM1 | c.1560G>T p.L520= | Silent (SNP) | VAF 6/40 reads (15%) | called by muse, mutect2, varscan2
- LLGL1 | c.153C>T p.I51= | Silent (SNP) | VAF 43/170 reads (25%) | catalogued as rs145857913; called by muse, mutect2, varscan2
- LPO | c.1473C>A p.L491= | Silent (SNP) | VAF 74/416 reads (18%) | called by muse, varscan2
- LVRN | c.2952G>A p.A984= | Silent (SNP) | VAF 521/665 reads (78%) | catalogued as rs373152073; called by muse, mutect2, varscan2
- LZTS3 | c.1104G>A p.R368= | Silent (SNP) | VAF 29/98 reads (30%) | called by muse, mutect2, varscan2
- MACF1 | c.5703G>A p.E1901= | Silent (SNP) | VAF 87/322 reads (27%) | called by muse, mutect2, varscan2
- MRM3 | c.681G>T p.L227= | Silent (SNP) | VAF 78/346 reads (23%) | called by muse, mutect2, varscan2
- MROH5 | c.1818G>C p.V606= | Silent (SNP) | VAF 157/433 reads (36%) | called by muse, mutect2, varscan2
- MXRA5 | c.3756G>A p.A1252= | Silent (SNP) | VAF 65/231 reads (28%) | catalogued as rs756235173; called by muse, mutect2, varscan2
- MYBPC3 | c.2397C>A p.G799= | Silent (SNP) | VAF 22/91 reads (24%) | called by muse, mutect2, varscan2
- MYH4 | c.330C>T p.Y110= | Silent (SNP) | VAF 159/523 reads (30%) | catalogued as rs756653851; called by muse, mutect2, varscan2
- NAV3 | c.3372G>T p.V1124= | Silent (SNP) | VAF 286/524 reads (55%) | catalogued as COSV57074549; called by muse, mutect2, varscan2
- NMBR | c.30G>T p.S10= | Silent (SNP) | VAF 111/170 reads (65%) | called by muse, mutect2, varscan2
- NUBPL | c.792G>A p.Q264= | Silent (SNP) | VAF 309/842 reads (37%) | catalogued as COSV55268569; called by muse, mutect2, varscan2
- NXNL1 | c.399C>T p.L133= | Silent (SNP) | VAF 26/143 reads (18%) | called by muse, mutect2, varscan2
- ODF4 | c.477C>T p.L159= | Silent (SNP) | VAF 39/158 reads (25%) | called by muse, mutect2, varscan2
- OR11H1 | c.843C>T p.F281= | Silent (SNP) | VAF 37/176 reads (21%) | catalogued as rs1259875111; called by mutect2, varscan2
- OR2G3 | c.555C>T p.L185= | Silent (SNP) | VAF 62/384 reads (16%) | catalogued as COSV60683249; called by muse, mutect2, varscan2
- OR2Y1 | c.117C>G p.L39= | Silent (SNP) | VAF 106/1560 reads (7%) | called by muse, mutect2
- OR5AS1 | c.324T>A p.A108= | Silent (SNP) | VAF 75/130 reads (58%) | called by muse, mutect2, varscan2
- OVCH1 | c.609G>A p.A203= | Silent (SNP) | VAF 73/340 reads (21%) | catalogued as rs376880639; called by muse, mutect2, varscan2
- PCDHA10 | c.513C>G p.L171= | Silent (SNP) | VAF 366/751 reads (49%) | catalogued as COSV56478108; called by muse, mutect2, varscan2
- PCDHGB6 | c.1194C>A p.S398= | Silent (SNP) | VAF 384/506 reads (76%) | called by muse, mutect2, varscan2
- PPFIA1 | c.12G>A p.E4= | Silent (SNP) | VAF 76/145 reads (52%) | called by muse, mutect2, varscan2
- PPP4R3C | c.1330C>T p.L444= | Silent (SNP) | VAF 17/363 reads (5%) | called by muse, mutect2
- PRAMEF15 | c.882G>C p.L294= | Silent (SNP) | VAF 48/540 reads (9%) | called by muse, mutect2
- PTGES3L-AARSD1 | c.450C>T p.V150= (on ENST00000421990 / NM_001136042.2; = p.V132= on NM_025267.3) | Silent (SNP) | VAF 97/529 reads (18%) | called by muse, mutect2, varscan2
- PTHLH | c.189G>C p.L63= | Silent (SNP) | VAF 56/237 reads (24%) | called by muse, mutect2, varscan2
- PTPRH | c.642G>C p.L214= | Silent (SNP) | VAF 25/134 reads (19%) | called by muse, mutect2, varscan2
- PUS7 | c.273G>A p.E91= | Silent (SNP) | VAF 298/396 reads (75%) | catalogued as rs752320733; called by muse, mutect2, varscan2
- PWWP2B | c.111G>A p.L37= | Silent (SNP) | VAF 21/38 reads (55%) | catalogued as rs774165126; called by muse, mutect2, varscan2
- RAD18 | c.204A>G p.T68= | Silent (SNP) | VAF 44/194 reads (23%) | catalogued as rs761228149, COSV99368630; called by muse, mutect2, varscan2
- RBL1 | c.3018C>T p.F1006= | Silent (SNP) | VAF 30/154 reads (19%) | called by muse, mutect2, varscan2
- SCN2A | c.855T>C p.N285= | Silent (SNP) | VAF 94/490 reads (19%) | called by muse, mutect2, varscan2
- SH3TC1 | c.2307C>T p.L769= | Silent (SNP) | VAF 34/152 reads (22%) | called by muse, mutect2, varscan2
- SIRPA | c.33C>T p.L11= | Silent (SNP) | VAF 37/150 reads (25%) | catalogued as COSV100605329; called by muse, mutect2, varscan2
- SLC12A9 | c.2382C>T p.I794= | Silent (SNP) | VAF 20/115 reads (17%) | called by muse, mutect2, varscan2
- SLC6A3 | c.360C>T p.L120= | Silent (SNP) | VAF 82/673 reads (12%) | catalogued as rs148447720; ClinVar: likely benign; called by muse, mutect2, varscan2
- SORCS3 | c.1971G>T p.G657= | Silent (SNP) | VAF 58/131 reads (44%) | called by muse, mutect2, varscan2
- SPAG9 | c.459G>A p.K153= | Silent (SNP) | VAF 49/320 reads (15%) | catalogued as COSV56234256; called by muse, mutect2, varscan2
- TBL3 | c.1659C>T p.F553= | Silent (SNP) | VAF 64/433 reads (15%) | called by muse, mutect2, varscan2
- TGIF2LX | c.531G>T p.S177= | Silent (SNP) | VAF 883/1350 reads (65%) | called by muse, mutect2, varscan2
- TLE4 | c.1158G>A p.L386= | Silent (SNP) | VAF 139/489 reads (28%) | called by muse, varscan2
- TMEM106C | c.588G>A p.P196= | Silent (SNP) | VAF 68/372 reads (18%) | catalogued as rs369092568; called by muse, mutect2, varscan2
- TPP2 | c.2847C>T p.F949= | Silent (SNP) | VAF 40/87 reads (46%) | called by muse, mutect2, varscan2
- TRHDE | c.18C>G p.A6= | Silent (SNP) | VAF 17/52 reads (33%) | called by muse, mutect2, varscan2
- TSNAXIP1 | c.564C>G p.L188= | Silent (SNP) | VAF 72/379 reads (19%) | catalogued as COSV99534767; called by muse, mutect2, varscan2
- TSPAN11 | c.447C>A p.L149= | Silent (SNP) | VAF 91/371 reads (25%) | called by muse, mutect2, varscan2
- UST | c.171C>T p.V57= | Silent (SNP) | VAF 68/246 reads (28%) | catalogued as rs752057970; called by muse, mutect2, varscan2
- WAS | c.687G>T p.G229= | Silent (SNP) | VAF 101/351 reads (29%) | catalogued as CS101175; called by muse, mutect2, varscan2
- WDFY1 | c.81C>T p.V27= | Silent (SNP) | VAF 57/286 reads (20%) | called by muse, varscan2
- ZNF331 | c.579G>T p.G193= | Silent (SNP) | VAF 47/250 reads (19%) | catalogued as COSV99466798; called by muse, mutect2, varscan2
- ZNF880 | c.111G>T p.V37= | Silent (SNP) | VAF 105/243 reads (43%) | called by muse, mutect2, varscan2
- AC104078.1 | n.188C>G | RNA (SNP) | VAF 129/559 reads (23%) | called by muse, mutect2, varscan2
- ACADS | chr12:120725775 G>A | 5'Flank (SNP) | VAF 18/97 reads (19%) | called by muse, mutect2, varscan2
- AL353804.4 | chrX:73825951 G>A | 5'Flank (SNP) | VAF 128/576 reads (22%) | called by muse, mutect2, varscan2
- ARPP19 | c.-54C>T | 5'UTR (SNP) | VAF 59/220 reads (27%) | catalogued as rs953406710; called by muse, mutect2, varscan2
- ATM | c.4909+50G>C | Intron (SNP) | VAF 47/196 reads (24%) | called by muse, mutect2, varscan2
- ATP1A3 | c.3053-62C>A | Intron (SNP) | VAF 301/731 reads (41%) | called by muse, mutect2, varscan2
- B3GNTL1 | c.409-400G>T | Intron (SNP) | VAF 142/450 reads (32%) | called by muse, mutect2, varscan2
- CD34 | c.598-240C>G | Intron (SNP) | VAF 38/164 reads (23%) | catalogued as rs763109385; called by muse, varscan2
- CFL2 | c.*2212dup | 3'UTR (INS) | VAF 14/96 reads (15%) | called by mutect2, varscan2
- CHCHD3 | c.170-10911C>T | Intron (SNP) | VAF 181/1801 reads (10%) | called by muse, mutect2, varscan2
- CIAO3 | c.163-308C>T | Intron (SNP) | VAF 160/412 reads (39%) | catalogued as rs1401959150; called by muse, mutect2, varscan2
- COL5A1 | c.5136+98C>A | Intron (SNP) | VAF 91/277 reads (33%) | called by muse, mutect2, varscan2
- COX7A2 | c.204+38A>G | Intron (SNP) | VAF 9/29 reads (31%) | called by muse, mutect2
- CTAGE13P | chr6:168294142 G>T | 5'Flank (SNP) | VAF 199/672 reads (30%) | called by muse, mutect2, varscan2
- DELEC1 | n.694C>G | RNA (SNP) | VAF 58/215 reads (27%) | catalogued as COSV64983440; called by muse, mutect2
- ETS1 | chr11:128527087 G>T | 5'Flank (SNP) | VAF 21/46 reads (46%) | called by muse, varscan2
- FKBP10 | c.1256+41C>T | Intron (SNP) | VAF 60/170 reads (35%) | called by muse, mutect2, varscan2
- FKBP6 | c.-185G>T | 5'UTR (SNP) | VAF 172/370 reads (46%) | called by muse, mutect2, varscan2
- FLJ40288 | n.746C>T | RNA (SNP) | VAF 133/390 reads (34%) | called by muse, varscan2
- FLJ40288 | n.818C>T | RNA (SNP) | VAF 189/509 reads (37%) | called by muse, varscan2
- FRG2KP | chr16:31569346 A>G | 5'Flank (SNP) | VAF 42/216 reads (19%) | called by muse, varscan2
- GALNT13 | c.1396-760C>T | Intron (SNP) | VAF 15/36 reads (42%) | catalogued as rs1485205423; called by muse, mutect2, varscan2
- H2BC18 | c.378-9679T>G | Intron (SNP) | VAF 140/446 reads (31%) | called by muse, mutect2, varscan2
- HMGN2P46 | n.1158C>T | RNA (SNP) | VAF 77/204 reads (38%) | called by muse, mutect2, varscan2
- INPP4A | c.2801+4574G>C | Intron (SNP) | VAF 187/414 reads (45%) | called by muse, mutect2, varscan2
- ITGAX | c.-6C>T | 5'UTR (SNP) | VAF 71/427 reads (17%) | catalogued as rs1273595472; called by muse, mutect2, varscan2
- KIF16B | c.3498+3159G>A | Intron (SNP) | VAF 120/648 reads (19%) | called by muse, mutect2, varscan2
- KRT17P2 | n.646G>C | RNA (SNP) | VAF 89/529 reads (17%) | called by muse, mutect2, varscan2
- LINC01551 | n.1254+18603G>C | Intron (SNP) | VAF 46/298 reads (15%) | called by muse, mutect2, varscan2
- LRRC37BP1 | n.1180A>T | RNA (SNP) | VAF 60/524 reads (11%) | catalogued as rs769342909; called by muse, mutect2, varscan2
- LTO1 | c.50+57C>G | Intron (SNP) | VAF 27/115 reads (23%) | catalogued as COSV99654047; called by muse, mutect2, varscan2
- MTRNR2L1 | c.*9G>T | 3'UTR (SNP) | VAF 104/231 reads (45%) | called by muse, mutect2, varscan2
- NCOA2 | c.*39C>T | 3'UTR (SNP) | VAF 39/137 reads (28%) | called by muse, mutect2, varscan2
- NXF5 | n.1378G>T | RNA (SNP) | VAF 50/646 reads (8%) | catalogued as COSV99534716; called by muse, mutect2
- OR2W5 | n.737A>T | RNA (SNP) | VAF 137/468 reads (29%) | called by muse, mutect2, varscan2
- PFKFB4 | chr3:48559529 T>C | 5'Flank (SNP) | VAF 41/252 reads (16%) | catalogued as rs1433357117; called by muse, mutect2, varscan2
- PLCB4 | c.*19G>A | 3'UTR (SNP) | VAF 93/399 reads (23%) | catalogued as COSV53798431; called by muse, mutect2, varscan2
- POLD2 | c.-28G>T | 5'UTR (SNP) | VAF 86/223 reads (39%) | called by muse, varscan2
- PRPF8 | c.*44C>G | 3'UTR (SNP) | VAF 74/282 reads (26%) | called by muse, mutect2, varscan2
- PRRG2 | c.86-17C>T | Intron (SNP) | VAF 21/123 reads (17%) | called by muse, mutect2, varscan2
- PRRT1 | c.20-184G>T | Intron (SNP) | VAF 98/353 reads (28%) | called by muse, mutect2, varscan2
- PTPRN | c.115+249G>A | Intron (SNP) | VAF 122/592 reads (21%) | catalogued as rs1412139963; called by muse, mutect2, varscan2
- REG3A | c.-10C>G | 5'UTR (SNP) | VAF 48/222 reads (22%) | called by muse, mutect2, varscan2
- RGS5 | c.45-4221A>T | Intron (SNP) | VAF 76/207 reads (37%) | called by muse, varscan2
- RXFP3 | c.*1C>A | 3'UTR (SNP) | VAF 67/80 reads (84%) | catalogued as COSV57506493; called by muse, mutect2, varscan2
- SCNN1A | c.417-45C>T | Intron (SNP) | VAF 12/36 reads (33%) | catalogued as COSV99964563; called by muse, mutect2, varscan2
- SCNN1D | c.-449C>T | 5'UTR (SNP) | VAF 30/205 reads (15%) | called by muse, mutect2, varscan2
- SEPTIN6 | chrX:119616546 A>T | 3'Flank (SNP) | VAF 22/358 reads (6%) | called by muse, mutect2
- SLC11A2 | c.122-494G>C | Intron (SNP) | VAF 18/77 reads (23%) | called by muse, mutect2, varscan2
- SLC25A11 | c.95+17G>T | Intron (SNP) | VAF 93/503 reads (18%) | called by muse, mutect2, varscan2
- SLCO1B3-SLCO1B7 | c.1866-47943G>T | Intron (SNP) | VAF 88/192 reads (46%) | catalogued as rs754338081, COSV67442734, COSV67447894; called by muse, mutect2, varscan2
- SNORD113-5 | n.6C>T | RNA (SNP) | VAF 64/280 reads (23%) | called by muse, mutect2, varscan2
- SYT14 | chr1:210163982 C>A | 3'Flank (SNP) | VAF 56/130 reads (43%) | called by muse, mutect2, varscan2
- TAZ | c.*404G>A | 3'UTR (SNP) | VAF 86/812 reads (11%) | called by muse, mutect2
- TRIM41 | c.813+67G>T | Intron (SNP) | VAF 51/492 reads (10%) | called by muse, mutect2, varscan2
- TTYH1 | chr19:54415226 C>T | 5'Flank (SNP) | VAF 63/481 reads (13%) | called by muse, mutect2, varscan2
- UNK | c.-16G>A | 5'UTR (SNP) | VAF 120/286 reads (42%) | called by muse, mutect2, varscan2
- USF2 | c.110-9C>G | Intron (SNP) | VAF 55/305 reads (18%) | catalogued as rs762695864; called by muse, mutect2, varscan2
- WNT10A | c.*25G>A | 3'UTR (SNP) | VAF 16/54 reads (30%) | catalogued as rs974286327; called by muse, mutect2, varscan2
- XPO5 | c.2678-353G>C | Intron (SNP) | VAF 83/220 reads (38%) | called by muse, mutect2, varscan2
- ZIK1 | c.33+16A>G | Intron (SNP) | VAF 46/172 reads (27%) | called by muse, mutect2, varscan2
- ZNF658B | n.2151G>A | RNA (SNP) | VAF 134/452 reads (30%) | called by muse, mutect2, varscan2
- ZNF658B | n.2018G>C | RNA (SNP) | VAF 131/438 reads (30%) | called by muse, mutect2, varscan2
- ZNF714 | c.*886G>C | 3'UTR (SNP) | VAF 24/110 reads (22%) | called by muse, mutect2, varscan2
- ZNF99 | c.*651C>A | 3'UTR (SNP) | VAF 123/176 reads (70%) | called by muse, varscan2
- ZSCAN32 | c.915-106G>A | Intron (SNP) | VAF 132/420 reads (31%) | catalogued as COSV100514233; called by muse, mutect2, varscan2
